Gene-level copy-number profile of tumor specimen TCGA-CV-A45R-01A from TCGA case TCGA-CV-A45R, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 46.9 years (17,125 days).
Specimen TCGA-CV-A45R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d502f7fa-72df-4055-a5fd-45292d4062e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A45R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5623b74d-b991-43c0-b8a2-31319dd3b463

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 214; copy number 2: 12,106; copy number 3: 26,154; copy number 4: 16,800; copy number 5: 1,620; copy number 6: 1,714; copy number 7: 299; copy number 8: 756; copy number 9: 69; copy number 12: 25; copy number 19: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A45R-01A-11D-A24C-01): tumor purity 0.43, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:97,901,653–97,902,288, 1 gene: RPL7AP61.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,204 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,736,711–51,623,428, 205 genes, copy number 7–19 (broad region; genes not listed).
- chr8:30,384,511–46,907,309, 271 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr10:43,194,535–43,981,102, 31 genes, copy number 7 (within-gene range 3–7): RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1, SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1.
- chr12:108,434,130–133,214,832, 697 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
